Somatic mutation profile of tumor specimen ALCH-B1KU-TTP1-A (aliquot ALCH-B1KU-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1KU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.4 years (22,801 days).
Specimen ALCH-B1KU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26db2072-e5f2-4f1b-8272-457eea8c927c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KU-NB1-A (Blood Derived Normal), aliquot ALCH-B1KU-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9300dfe2-12ce-44a8-9759-0808746641b9

The open-access MAF lists 58 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 11, Intron 2, 5'UTR 2, Frame Shift Ins 1, 3'UTR 1, Splice Site 1, In Frame Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 106/412 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs483352697, CM984587, COSV52667931, COSV52674826, COSV52678297; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 27/542 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as rs1446626717; called by muse, mutect2
- CDH12 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 10/275 reads (4%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.999); catalogued as COSV66426630; called by muse, mutect2
- CENPJ | c.3505C>T p.R1169C | Missense Mutation (SNP) | VAF 46/608 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs571084331, COSV55035118; called by muse, mutect2
- DPEP2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as rs1487068051, COSV52056007; called by muse, mutect2
- EGFR | c.2239_2251delinsC p.L747_T751delinsP | In Frame Del (DEL) | VAF 115/594 reads (19%) | catalogued as rs397509368, COSV51765856; ClinVar: drug response; called by pindel, varscan2*
- GRIP2 | c.395G>A p.R132H (on ENST00000619221; = p.R35H on NM_001080423.4) | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs867596557; called by muse, mutect2, varscan2
- HCRTR2 | c.1184C>A p.T395N | Missense Mutation (SNP) | VAF 142/571 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV63795987; called by muse, mutect2, varscan2
- HECW1 | c.4153G>A p.E1385K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as rs1246385704; called by muse, mutect2
- IFIH1 | c.539C>A p.A180E | Missense Mutation (SNP) | VAF 23/456 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV55124844; called by muse, mutect2
- KIAA1210 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as rs375401704; called by muse, mutect2, varscan2
- MROH1 | c.4111C>T p.R1371C | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1037897953; called by muse, mutect2
- SEPTIN5 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs750628669, COSV63530928; called by muse, mutect2
- SLFN12L | c.28A>C p.N10H (on ENST00000260908 / NM_001363830.1; = p.N28H on NM_001195790.1) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.598); catalogued as COSV99610186; called by muse, mutect2
- TNR | c.3829T>C p.S1277P | Missense Mutation (SNP) | VAF 94/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99687242; called by muse, mutect2, varscan2
- ABCC11 | c.638A>C p.E213A | Missense Mutation (SNP) | VAF 27/547 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2
- ACTG1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); called by muse, mutect2
- ADAMTS19 | c.3359G>C p.C1120S | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2
- AKNAD1 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2
- CCL7 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2
- CD1C | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 22/688 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2
- CYFIP1 | c.1747A>C p.S583R | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2
- DDX3Y | c.1651A>G p.T551A | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- DTHD1 | c.785A>G p.N262S (on ENST00000456874; = p.N97S on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- EXPH5 | c.4216T>G p.S1406A | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- FNIP2 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GAN | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 36/632 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2
- HSFX1 | c.101A>C p.Q34P | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- LILRA2 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 18/314 reads (6%) | called by muse, mutect2
- LOXL4 | c.2189A>G p.N730S | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- NDUFAF7 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 58/670 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.4); called by muse, mutect2
- OGDH | c.2179+1G>A p.X727_splice | Splice Site (SNP) | VAF 58/151 reads (38%) | called by muse, mutect2, varscan2
- OR4A15 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 34/568 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.323); called by muse, mutect2
- PSMD1 | c.1206dup p.T403Yfs*11 | Frame Shift Ins (INS) | VAF 32/232 reads (14%) | called by mutect2, pindel, varscan2
- RREB1 | c.3616G>T p.D1206Y | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- SCLT1 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- TFAP2C | c.809A>G p.K270R | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2
- TIRAP | c.617T>G p.F206C | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRPC6 | c.1546C>G p.Q516E | Missense Mutation (SNP) | VAF 23/529 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- ZBED1 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF716 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2
- DMD | c.2478G>A p.L826= | Silent (SNP) | VAF 37/356 reads (10%) | called by muse, mutect2, varscan2
- DNAH11 | c.4260G>A p.K1420= | Silent (SNP) | VAF 45/739 reads (6%) | catalogued as rs751806796; called by muse, mutect2
- HP1BP3 | c.1566C>T p.G522= | Silent (SNP) | VAF 15/458 reads (3%) | called by muse, mutect2
- OR4A15 | c.624C>A p.T208= | Silent (SNP) | VAF 38/486 reads (8%) | catalogued as rs761843525, COSV59035493; called by muse, mutect2
- PMEPA1 | c.729C>T p.S243= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- RESF1 | c.1761G>A p.L587= | Silent (SNP) | VAF 9/163 reads (6%) | catalogued as rs1343868640; called by muse, mutect2
- SMIM10 | c.252G>A p.*84= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, varscan2
- SYNGAP1 | c.207C>A p.I69= | Silent (SNP) | VAF 29/241 reads (12%) | catalogued as rs1277574462; called by muse, mutect2, varscan2
- TMEM132B | c.2442C>T p.L814= | Silent (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- VWF | c.162G>A p.A54= | Silent (SNP) | VAF 34/436 reads (8%) | catalogued as rs148741727; called by muse, mutect2
- ZFYVE27 | c.255C>T p.L85= | Silent (SNP) | VAF 59/511 reads (12%) | catalogued as rs767037495; called by muse, mutect2, varscan2
- ANXA10 | c.*13T>G | 3'UTR (SNP) | VAF 15/156 reads (10%) | called by muse, mutect2
- FAM90A20P | n.1076T>C | RNA (SNP) | VAF 19/285 reads (7%) | catalogued as rs775568781; called by muse, mutect2
- GH2 | c.-22G>T | 5'UTR (SNP) | VAF 21/392 reads (5%) | called by muse, mutect2
- HGFAC | c.1103-135G>A | Intron (SNP) | VAF 20/163 reads (12%) | catalogued as rs746962267, COSV66977066; called by muse, mutect2, varscan2
- RIDA | c.-44G>T | 5'UTR (SNP) | VAF 13/296 reads (4%) | called by muse, mutect2
- YIPF3 | c.395+329G>T | Intron (SNP) | VAF 16/294 reads (5%) | catalogued as rs1383044718, COSV104411955; called by muse, mutect2
